CPTAC case C3N-03796 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/76a8fbb7-fbfd-48e8-868f-18e2092f5a6f

Demographics
Sex at birth: male; Race: asian; Year of birth: 1962; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 55.9 years (20,425 days); Year of diagnosis: 2018; Last known disease status: Tumor free; Days to last known disease status: 730 days (2.0 years); Progression or recurrence: no; Days to last follow up: 730 days (2.0 years).
   Pathology details: Greatest tumor dimension: 4 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 371 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 730 days (2.0 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 2.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03796-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 130 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03796-21: Section location: Right Frontal and Right Parietal Lobe; Percent tumor nuclei: 60; Percent necrosis: 55.
- Sample C3N-03796-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
